Surgical pathology report (de-identified scan), TCGA case TCGA-CW-5590, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-CW-5590-01A (Primary Tumor).

TISSUE DESCRIPTION:

Right kidney (485 grams, 11.3 x 8.0 x 8.0 cm), portion right adrenal (1.0 x 0.8 x 0.5 cm) and 9.5 cm ureter

DIAGNOSIS:

Kidney, right, radical nephrectomy: Grade 3 (of 4) renal cell carcinoma, clear cell type, forming a 10.0 x 9.0 x 6.0 cm mass located in the anterior lower pole of the kidney. The tumor extends into the perinephric fat. The renal vein is free of tumor. The tumor does not involve the collecting system. Coagulative tumor necrosis is present. Sarcomatoid differentiation is absent. The surgical margins are negative. There are (11) additional separate renal cell carcinomas, clear cell type, grade 1-2 (of 4) forming tumor nodules ranging in size from 0.4 to 1.5 cm in greatest dimension, scattered in the upper and mid portion of the kidney. No renal hilar lymph nodes are identified.. The adrenal is unremarkable.

Source: NCI Genomic Data Commons file 1c1b0612-c0e0-47a8-8bc4-389715a6d496 (TCGA-CW-5590.0BC280C6-AC1C-4BFB-AE13-54357F7D8928.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).